Somatic mutation profile of tumor specimen TCGA-EL-A3TA-01A (aliquot TCGA-EL-A3TA-01A-12D-A22D-08) from TCGA case TCGA-EL-A3TA, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 42.1 years (15,366 days).
Specimen TCGA-EL-A3TA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d95af550-db2c-49ce-96f8-885da2eadef7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3TA-11A (Solid Tissue Normal), aliquot TCGA-EL-A3TA-11A-12D-A22D-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db8a6518-fa3e-4ee8-a877-c99df5cc2bb2

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/52 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- DCDC2 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 11/60 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV51239931; called by muse, mutect2, varscan2
- PITPNM3 | c.1986G>A p.M662I | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV52598539; called by muse, mutect2, varscan2
- ZSCAN18 | c.1266C>T p.F422= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as rs1457428281, COSV53732804; called by muse, mutect2
